Gene-level copy-number profile of tumor specimen TCGA-06-2567-01A from TCGA case TCGA-06-2567, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.0 years (23,759 days).
Specimen TCGA-06-2567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.63eb9a48-14dd-45be-818e-e88ecd813ebd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-2567-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0716525-4072-47d2-9d0c-5db0c3b3e0cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 7,646; copy number 2: 49,094; copy number 3: 3,065.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-2567-01A-01D-0784-01): tumor purity 0.8, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,398,825–51,158,471, 15 genes: HMGB1P45, FCF1P6, DMRTA2, AL049637.1, FAF1, FAF1-AS1, RNU6-1026P, PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500, C1orf185, Y_RNA, CFL1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,266. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
